Somatic mutation profile of tumor specimen 1105201 (aliquot 7316UP-979-1105201) from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105201: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d077de1-e34a-420c-893e-c6a34d407bd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105214 (Blood Derived Normal), aliquot 7316UP-613-1105214; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6942f1a-750f-4268-ad99-01fd05084712

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 2, Intron 2, 5'UTR 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.7600C>T p.R2534* | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | catalogued as rs145143533, CM051005; ClinVar: benign; called by muse, mutect2
- BAIAP2 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs943691615; called by muse, mutect2, varscan2
- EDC4 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1214063850; called by muse, mutect2, varscan2
- FLG | c.7407C>G p.S2469R | Missense Mutation (SNP) | VAF 107/684 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as rs771465526; called by muse, mutect2, varscan2
- MUC17 | c.8401C>A p.P2801T | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs753157006, COSV60292298; called by muse, mutect2
- MUC4 | c.3575C>G p.S1192* | Nonsense Mutation (SNP) | VAF 52/556 reads (9%) | catalogued as rs1181202036; called by muse, mutect2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 53/504 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2, varscan2
- OTOA | c.1138G>A p.V380I (on ENST00000286149; = p.V366I on NM_144672.4) | Missense Mutation (SNP) | VAF 51/433 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs764772897, COSV53750352; called by muse, mutect2, varscan2
- POU5F1B | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.287); catalogued as COSV101197017; called by muse, mutect2, varscan2
- SHROOM3 | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV56026958; called by muse, mutect2, varscan2
- SUFU | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64015566; called by muse, mutect2, varscan2
- SVEP1 | c.7535C>T p.T2512M | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs200375910; called by muse, mutect2, varscan2
- TMEM200A | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs1032893688, COSV51661039; called by muse, mutect2, varscan2
- TRPV5 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs775179978, COSV54688182; called by muse, mutect2, varscan2
- VIT | c.1495G>A p.V499I (on ENST00000389975 / NM_001177969.1; = p.V514I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs773111980, COSV64899202; called by muse, mutect2, varscan2
- ZFP64 | c.1756C>G p.L586V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs371444820, COSV53803673; called by muse, mutect2
- ANKRD40 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CCDC50 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDK17 | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- GRID2 | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2
- ITGAL | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2
- LSR | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRM3 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPH1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); called by muse, mutect2
- BCL2L10 | c.42G>A p.P14= | Silent (SNP) | VAF 30/446 reads (7%) | catalogued as rs1027707660; called by muse, mutect2
- CRB2 | c.579C>T p.C193= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as rs758424803; called by muse, mutect2, varscan2
- GOLGA8H | c.567C>A p.A189= | Silent (SNP) | VAF 50/646 reads (8%) | called by muse, mutect2
- GRHL3 | c.1233C>T p.D411= (on ENST00000350501 / NM_198174.3; = p.D416= on NM_021180.3) | Silent (SNP) | VAF 24/259 reads (9%) | catalogued as rs140971496; called by muse, mutect2
- GRM8 | c.1536G>A p.P512= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as rs774632571, COSV58809093, COSV58817276, COSV58852761; called by muse, mutect2
- MSH2 | c.2400A>G p.L800= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs201298777; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- OR6C6 | c.315G>A p.P105= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as rs751973071; called by muse, mutect2, varscan2
- PLEKHG3 | c.1986C>T p.D662= (on ENST00000394691; = p.D718= on NM_001308147.2) | Silent (SNP) | VAF 49/402 reads (12%) | called by muse, mutect2, varscan2
- SPHKAP | c.1986C>T p.V662= | Silent (SNP) | VAF 19/207 reads (9%) | catalogued as rs61752224, COSV60872785; called by muse, mutect2
- ZC3H12B | c.564C>T p.D188= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, varscan2
- HBEGF | c.-25C>T | 5'UTR (SNP) | VAF 10/310 reads (3%) | called by muse, mutect2
- KLC2 | c.*328C>T | 3'UTR (SNP) | VAF 59/433 reads (14%) | catalogued as rs1224502861; called by muse, mutect2, varscan2
- MTRNR2L9 | n.67C>T | RNA (SNP) | VAF 12/88 reads (14%) | catalogued as rs1180018123; called by muse, mutect2
- NCAM1 | c.2456+1105C>T | Intron (SNP) | VAF 36/249 reads (14%) | called by muse, mutect2, varscan2
- SPINK9 | c.87+30T>C | Intron (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
